Gene-level copy-number profile of tumor specimen ALCH-B4N9-TTP1-A from ALCHEMIST case ALCH-B4N9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.4 years (23,166 days).
Specimen ALCH-B4N9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a9a05296-2c8a-4172-8390-a6503bf13f43.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4N9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/122f5a38-b51a-40a5-bfbe-cc27faab7c2e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 1,327; copy number 2: 8,186; copy number 3: 10,892; copy number 4: 15,198; copy number 5: 14,045; copy number 6: 5,264; copy number 7: 2,600; copy number 8: 852; copy number 11: 4; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:151,814,073–151,828,488, 1 gene (within-gene range 0–6): AADAC.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–3): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:101,330,302–102,074,812, 7 genes (within-gene range 0–3): MIR1255A, FLJ20021, BANK1, AC084277.1, RNU6-462P, MTND5P5, AP002075.1.
- chr5:100,062,275–100,067,954, 1 gene: GUSBP7.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr21:44,200,602–44,207,399, 1 gene: AP001057.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 11 (within-gene range 3–11): TTC34, AC242022.2, AC242022.1.
- chr7:7,066,964–7,067,045, 1 gene, copy number 12: MIR3683.
- chr20:13,785,007–13,996,443, 3 genes, copy number 12 (within-gene range 7–12): NDUFAF5, SEL1L2, RNU6-278P.
- chr20:32,358,330–32,439,319, 1 gene, copy number 11: ASXL1.

Autosomal genes at a single copy (total copy number 1): 1,322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
